Somatic mutation profile of tumor specimen TCGA-VN-A88R-01A (aliquot TCGA-VN-A88R-01A-11D-A364-08) from TCGA case TCGA-VN-A88R, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 53.4 years (19,513 days).
Specimen TCGA-VN-A88R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15e50abc-9870-4544-88a9-2c0ccf772172.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VN-A88R-10B (Blood Derived Normal), aliquot TCGA-VN-A88R-10B-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4d50402-ed1c-4ff0-8c39-75e79f9a33a4

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.373T>C p.F125L | Missense Mutation (SNP) | VAF 43/95 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100753178, COSV100753463, COSV61654162; called by muse, mutect2, varscan2
- ADAMTS8 | c.1899C>A p.S633R | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.151); catalogued as COSV99960389; called by muse, mutect2, varscan2
- BEST1 | c.1704A>C p.K568N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as COSV99861194; called by muse, mutect2, varscan2
- BMPR1A | c.771A>T p.K257N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as COSV100923317; called by muse, mutect2, varscan2
- CDH23 | c.7123T>C p.S2375P | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV99818949; called by muse, mutect2, varscan2
- CDH23 | c.7124C>A p.S2375* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV99818951; called by muse, mutect2, varscan2
- COL17A1 | c.394A>T p.R132* | Nonsense Mutation (SNP) | VAF 10/188 reads (5%) | catalogued as COSV100793050; called by muse, mutect2
- DAAM1 | c.1560+2T>C p.X520_splice | Splice Site (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100658160; called by muse, mutect2
- ELF4 | c.234T>G p.S78R | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.633); catalogued as COSV100257154; called by muse, mutect2, varscan2
- GPR37L1 | c.630+2T>C p.X210_splice | Splice Site (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100938520; called by muse, mutect2, varscan2
- HIPK4 | c.473A>C p.D158A | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99396375; called by muse, mutect2, varscan2
- IL36B | c.307C>A p.L103I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV99382480; called by muse, mutect2, varscan2
- L3HYPDH | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767958121, COSV99904334; called by muse, mutect2, varscan2
- PABPC3 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as rs760647633, COSV99879025; called by muse, varscan2
- PDPR | c.2173G>C p.D725H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1211037251, COSV99847772; called by muse, mutect2, varscan2
- RP1 | c.1463A>C p.E488A | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV99606304; called by muse, mutect2, varscan2
- USP12 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs1428611882, COSV99997416; called by muse, mutect2, varscan2
- XPC | c.1102C>A p.Q368K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99542080; called by muse, mutect2, varscan2
- ZNF713 | c.940T>G p.S314A (on ENST00000633730 / NM_001366796.2; = p.S327A on NM_182633.3) | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.297); catalogued as COSV101448708; called by muse, mutect2, varscan2
- RANBP2 | c.9273_9301del p.T3092Wfs*30 | Frame Shift Del (DEL) | VAF 22/108 reads (20%) | called by mutect2, pindel
- GPAT2 | c.1905C>T p.G635= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100853219; called by muse, mutect2, varscan2
- NDE1 | c.300C>G p.L100= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV100706719, COSV61273237; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1314C>G p.P438= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV56272644, COSV99837434; called by muse, mutect2, varscan2
- FAM174C | c.*325C>T | 3'UTR (SNP) | VAF 17/53 reads (32%) | catalogued as rs1440734364, COSV101331199; called by muse, mutect2, varscan2
